Surgical pathology report (de-identified scan), TCGA case TCGA-09-2048, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site UCSF, specimen TCGA-09-2048-01A (Primary Tumor).

[page 1 of 4]
SURGICAL PATHOLOGY REPORT

Service Date:

Sex: Female Received:

FINAL PATHOLOGIC DIAGNOSIS

A. Left ovary, oophorectomy: Papillary serous carcinoma, poorly differentiated with focal sarcoma pattern (carcinosarcoma), see comment.

Left fallopian tube, salpingectomy: Serous carcinoma, poorly differentiated, surface implant.

B. Right ovary, oophorectomy: Serous carcinoma, poorly differentiated, see comment.

C. Left periaortic lymph node, excision: Metastatic carcinoma identified in one of three nodes (1/3).

D. Uterus, hysterectomy:

Endometrium:

1. Inactive endometrium.

2. Benign endometrial polyp.

Myometrium: Leiomyomata.

Serosa: Metastatic serous carcinoma.

Cervix: Metastatic serous carcinoma in paracervical tissue.

Right fallopian tube, salpingectomy: Metastatic serous carcinoma.

E. Sigmoid colon, biopsy: Metastatic serous carcinoma.

F. Omentum, omentectomy: Metastatic serous carcinoma.

G. Periaortic lymph nodes, excision: No carcinoma identified in two nodes (0/2).

Page 1 of 4

H. Left pelvic lymph node, excision: Metastatic carcinoma identified in one node (1/1).

I. Right periaortic lymph nodes, excision: No carcinoma identified in two nodes (0/2).

J. Right pelvic lymph nodes, excision: Metastatic carcinoma identified in one of two nodes (1/2).

COMMENT:

Ovarian Tumor Synoptic Comment

Type of tumor: The tumor is predominantly serous carcinoma; however, extensive areas of solid growth are present and areas of endometrioid and clear cell patterns are noted. Additionally a focal 1.1 cm sarcomatous area (slides, A4,A5) is noted (see below for further discussion of this focus).

Grade of tumor: III.

Site of tumor: Bilateral.

Location of tumor: Intraovarian.

Condition of capsule: Indeterminate (the capsule of both ovaries arrived ruptured; it is not clear if the capsule was transected in the OR or if the capsule was ruptured).

Cut surface: Solid and cystic.

Necrosis: Moderate.

Lymphatic/vascular invasion: Lymphatic space invasion present.

Sites of metastasis in pelvis: Right and left fallopian tube, uterine serosal surface, paracervical soft tissue, sigmoid colon; maximum diameter of largest pelvic metastasis = 2.0 cm (adherent to right fallopian tube).

Pelvic lymph nodes: 2/3 lymph nodes with metastatic tumor.

Sites of metastasis in abdomen: Omentum; maximum diameter of largest abdominal metastasis = 8.0 cm.

Para-aortic lymph nodes: 0/3 lymph nodes with metastatic tumor.

Peritoneal cytology: (Ascitic fluid : Metastatic adenocarcinoma).

[page 2 of 4]
SURGICAL PATHOLOGY REPORT

Other abnormalities: None.

FIGO stage: IIIC.

TNM stage: pT3cN1Mx.

Comment: Immunoperoxidase stains were performed on the sarcomatous element. This focus stains strongly for vimentin and shows only focal staining for keratin. This staining pattern supports an interpretation of sarcoma rather than sarcomatoid carcinoma, thus a small (1.1 cm) sarcomatoid focus is present (carcinosarcoma). Given the small size of this focus, it will likely have little effect on the overall prognosis. _____ has reviewed this slide (A5) in the immunohistochemical results and concurs with this interpretation.

Specimen(s) Received

A: Left ovary (FS)

B: Right ovary

C: Periaortic lymph nodes, left (FS)

D: Uterus

E: Sigmoid Colon

F: Omentum

G: Peri-Aortic Lymph Nodes

H: Left Pelvic Lymph Nodes

I: Right Peri-Aortic Lymph Nodes

J: Right Pelvic Lymph Nodes

K: Ovary Blocks-

Intraoperative Diagnosis

Page 2 of 4

FS1 (A) Left ovary, oophorectomy: Poorly-differentiated carcinoma consistent with ovarian primary. concurs.

FS2 (C) Periaortic lymph nodes, left, excision: Metastatic carcinoma in one of two identified lymph nodes (1/2).

Clinical History

-year-old woman with ovarian carcinoma. TAH/BSO, lymph nodes, omentectomy.

Gross Description

Part A is received fresh and labeled "left ovary" and consists of a 14.0 x 12.0 x 5.5 cm lobulated, tan-white,

purple solid and cystic mass with generally smooth external surface, but rare surface nodules which are white-tan-yellow and focally confluent, up to 2.5 cm in aggregate, covering approximately 5% of the external

surface. A 9.5 cm irregular rupture or incision exposes soft, lobulated tan-red interior, focally cystic but generally solid. Additionally, there is an attached 7.5 x 1.0 cm diameter fallopian tube with fimbria which is

grossly unremarkable. Although the mass has been previously ruptured, an attempt is made to ink the surface. The cut surface reveals a proliferation with friable papillary areas, light tan necrotic areas, myxoid and yellow degenerate areas, multiple cystic cavities and occasional hemorrhagic foci. Tissue was removed for research. Sections:

Cassettes A1-A10: Sixteen sections of tumor including ovarian surface in A5-A9 and two cross-sections of fallopian tube in A7. Remainder from frozen section in A1.

Part B is submitted fresh and labeled "right ovary" and consists of a 12.0 x 7.0 x 5.0 cm semi-solid and cystic mass which has been opened by previously incision/rupture. The serosal surface is white, smooth, fibrous and shiny without grossly evident papillary lesions on the surface. The surface is inked black. The mass is solid and cystic with light tan papillary, friable areas of solid tumor, white light-tan fleshy areas and hemorrhagic and myxoid areas of necrosis. No fallopian tube is identified on the specimen. Sections: Cassettes B1-B6: Ten sections of tumor.

Part C is received fresh and labeled "periaortic lymph node" and consists of an elongate fragment of tan-yellow soft tissue measuring 6.2 x 1.4 x 1.1 cm. This specimen contains two tan-brown lymph nodes

[page 3 of 4]
SURGICAL PATHOLOGY REPORT

measuring 3.2 and 2.8 cm. The larger node contains an 0.8 cm white nodule. The smaller lymph node is unremarkable on sectioning. Sections:

Cassette C1: Part of the large node remaining from frozen section.

Cassette C2: Remainder from large node.

Cassette C3: Smaller lymph node remaining from frozen section.

Cassette C4: Remainder of tissue from small node (entire specimen submitted in C1-C4).

Part D is received in formalin and labeled "uterus" and consists of a 5.0 x 5.0 cm uterus with a 3.0 x 3.5 cm attached cervix. Additionally, an 8.0 x 1.0 cm right fallopian tube with markedly dilated, edematous 1.5

cm distal fallopian tube is noted. Adherent to the right fallopian tube is a 9.0 x 3.0 x 3.0 cm mass of papillary white, friable tumor. The fimbriated end of the fallopian tube is partially effaced by the carcinoma which forms an encasement around the fimbriated end. The anterior serosal surface of the uterus is granular with fine, micropapillary growth confluent over the entire anterior serosal uterine surface. Additionally, the white carcinomatous growth extends into the paracervical tissues bilaterally. The myometrium is 1.2 cm in thickness and the endometrial stripe is 0.1 cm in thickness. Near the cornu is a 1.0 x 1.2 x 0.2 cm polypoid, white whorling probable myoma extending into the endometrium.

Additionally

a polyp is present in the cornu. A 3.5 cm diameter hard, calcified myoma is present on the right lateral myometrial wall and a 1.1 cm diameter pedunculated, subserosal leiomyoma is present on the posterior surface of the uterus. Additionally, an intramural 1.5 cm leiomyoma is present in the posterior myometrial wall. Sections:

Cassette D1: Cervix @ 12 o'clock and 6 o'clock.

Cassette D2: Paracervical tissues.

Cassette D3: Complete cross-section of myometrial wall, including sub endometrial leiomyoma.

Cassette D4: Endometrial strips.

Cassette D5: Cross-sections from two posterior wall myomas.

Cassette D6: Anterior serosal surface and fallopian tube.

Page 3 of 4

Cassette D7: Two cross-sections of fallopian tube, including one with fimbriated end involved by tumor.

Cassette D8: Cross-section of tumor at right fallopian tube.

Part E is received in formalin and labeled "sigmoid colon" and consists of a 5.0 x 5.0 x 0.9, a 4.0 x 3.0 x 1.0 cm, a 2.5 x 1.5 x 0.5 cm fragments of soft tissue, including peritoneal surface and adipose tissue with white nodular tumor growth. Multiple cross-sections are submitted in cassette E1.

Part F is submitted in formalin and labeled "omentum" and consists of a 45.0 x 20.0 x 2.0 cm sheet of fibroadipose tissue with lobulated fat. At one edge of the omentum is an 8.0 x 5.0 x 2.5 cm area of firm induration and thickening with white nodular infiltration by carcinoma. A separate 0.7 cm discrete nodule, as well as a second 0.3 cm discrete nodule are identified. Sections from two discrete nodules and one section from larger nodule are submitted in cassette F1.

Part G is submitted in formalin and labeled "periaortic lymph node" and consists of a 2.0 x 1.0 x 0.5 cm fragment of fibroadipose tissue, submitted entirely in cassette G1.

Part H is submitted in formalin and labeled "pelvic lymph node - left" and consists of a 2.0 x 1.5 x 1.0 cm mass of fibrofatty tissue, entirely submitted in cassette H1.

Part I is submitted in formalin and labeled "aortic nodes, right" and consists of a 1.5 x 1.0 x 0.5 cm light tan mass of fibrofatty tissue, entirely submitted in cassette I1.

Part J is submitted in formalin and labeled "pelvic lymph node, right" and consists of a 3.0 x 1.0 x 0.5 cm mass of fibrofatty tissue and lymph nodes, entirely bisected and submitted in cassette J1 -2.

Part K, received for the , consists of three tan blocks, labeled "341-1, 341-2, and 341-3". All subsequently submitted as blocks "K1, K2, and K3".

The immunoperoxidase stain(s) reported above were developed and their performance characteristics determined by the

have not been cleared or approved by the U. S. Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary. These tests are used for clinical purposes. They should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 ("CLIA") as qualified to perform high-complexity clinical testing.

Diagnosis based on gross and microscopic examinations. Final diagnosis made by attending

[page 4 of 4]
URGICAL PATHOLOGY REPORT

pathologist following review of all pathology slides.

Electronically signed out on

Page 4 of 4

Source: NCI Genomic Data Commons file 1d96998f-3698-4881-8da6-6e44df3e93f9 (TCGA-09-2048.0755D708-ADF5-4219-ABC6-BCD9C2BCA089.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).